Somatic mutation profile of tumor specimen 0DRO3V from CCDI case PBCFGF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdoid tumor, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 1.9 years (708 days).
Specimen 0DRO3V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e534937-774a-4b76-8d9a-ff49b2884ce7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRO3I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd9213fd-b358-472b-bb59-1c6d68491e76

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4orf54 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 268/586 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs952392657, COSV104440100; called by muse, varscan2
- EIF3A | c.4145G>A p.R1382H | Missense Mutation (SNP) | VAF 311/693 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV60775413; called by muse, varscan2
- IGF2BP1 | c.286-34G>A | Intron (SNP) | VAF 190/362 reads (52%) | called by muse, varscan2
